Gene-level copy-number profile of tumor specimen TCGA-85-A50Z-01A from TCGA case TCGA-85-A50Z, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 57.3 years (20,941 days).
Specimen TCGA-85-A50Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.8328d1c3-4a2a-43e9-a3f3-89b351296b4b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-A50Z-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eccd84ee-c1dd-405c-a5ab-5dcf0cf9418e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 2: 17,972; copy number 3: 95; copy number 4: 36,984; copy number 5: 228; copy number 6: 3,077; copy number 7: 12; copy number 8: 268; copy number 9: 54; copy number 10: 477; copy number 11: 268; copy number 12: 194; copy number 14: 166; copy number 15: 2; copy number 27: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-A50Z-01A-21D-A25M-01): tumor purity 0.36, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:68,087,161–68,434,481, 7 genes: AC010376.1, RNU6-1232P, EEF1B2P2, LINC02219, PIK3R1, AC024579.1, AC010280.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,177 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:189,969,030–189,969,861, 1 gene, copy number 11: MTAPP2.
- chr5:58,198–33,522,230, 509 genes, copy number 11–14 (broad region; genes not listed).
- chr7:63,011,463–65,357,176, 130 genes, copy number 10 (broad region; genes not listed).
- chr8:35,862,123–43,674,591, 188 genes, copy number 9–27 (broad region; genes not listed).
- chr10:19,598,247–38,783,108, 347 genes, copy number 10 (broad region; genes not listed).
- chr11:24,455,911–24,456,010, 1 gene, copy number 15: Y_RNA.
- chr11:24,701,275–24,701,575, 1 gene, copy number 15: AC115990.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
